Somatic mutation profile of tumor specimen TARGET-10-PAPDLN-09A (aliquot TARGET-10-PAPDLN-09A-01D) from TARGET case TARGET-10-PAPDLN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (790 days).
Specimen TARGET-10-PAPDLN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6edd012-8279-4531-9ca1-44197dfeef99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDLN-14A (Bone Marrow Normal), aliquot TARGET-10-PAPDLN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/714c8f41-1072-4b7c-9a71-dc9acd956f64

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, 3'UTR 2, 5'UTR 2, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0A1 | c.2398C>A p.L800I (on ENST00000343619 / NM_001378531.1; = p.L794I on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52876115; called by muse, mutect2, varscan2
- FANCC | c.1511T>G p.I504S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV56659616; called by muse, mutect2, varscan2
- HOXA11 | c.811C>A p.R271S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99136131; called by muse, mutect2, varscan2
- INSYN2A | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV99040041; called by muse, mutect2, varscan2
- KMT5A | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs553535516, COSV57863154; called by muse, mutect2, varscan2
- PKD1 | c.10262C>T p.P3421L (on ENST00000262304 / NM_001009944.3; = p.P3420L on NM_000296.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs545053536, COSV99238362; called by muse, varscan2
- SVIL | c.5609G>A p.R1870Q (on ENST00000355867 / NM_021738.3; = p.R1444Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as rs762138005; called by muse, mutect2, varscan2
- UROD | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs552022258, COSV99870097; called by muse, mutect2, varscan2
- ZNF516 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1453758466; called by muse, mutect2, varscan2
- C14orf39 | c.1304A>G p.K435R | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CDH11 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IKZF1 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- MYH13 | c.2875G>A p.D959N | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MYOF | c.2409G>T p.E803D | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TENM1 | c.1750T>C p.W584R | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DERL1 | c.252G>A p.T84= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs763585570; called by muse, mutect2, varscan2
- SIM1 | c.906C>T p.G302= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs548536168, COSV53496595; called by muse, mutect2, varscan2
- H4C13 | c.*17C>G | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- NEDD1 | c.-56G>T | 5'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, varscan2
- SLC2A2 | c.*8del | 3'UTR (DEL) | VAF 44/92 reads (48%) | catalogued as rs573575421; ClinVar: uncertain significance / benign; called by mutect2, varscan2
- SLC66A1L | n.180C>A | RNA (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- SULT1B1 | c.-33A>G | 5'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
